CCG case CUPP-B7MO — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e81a5d4-b1ea-4453-bb1d-a0a180197900

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive; Country of birth: United States.

Diagnoses (2; GDC holds 3 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 2010; Prior malignancy: yes; Prior treatment: Yes.
2. Subsequent primary (histology not recorded by GDC).

Follow-up (1 entry)
- Days to follow up: 4,118 days (11.3 years); Year of follow up: 2021.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7MO-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7MO-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 64; Percent tumor nuclei: 28; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 34; Percent lymphocyte infiltration: 66; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
